Somatic mutation profile of tumor specimen 0DNWL2 from CCDI case PBCCBY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (540 days).
Specimen 0DNWL2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6966c85e-6119-4524-8af2-9512e2ea6184.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNWJL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d37de578-2c63-4c5f-99c6-393c170e6b8b

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PBDC1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 50/1095 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as rs782709186, COSV64896075; called by muse, mutect2
- SLIT2 | c.2605T>G p.W869G | Missense Mutation (SNP) | VAF 222/523 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIMM8A | c.216T>C p.D72= | Silent (SNP) | VAF 48/682 reads (7%) | catalogued as rs782344951; called by muse, mutect2
